Gene-level copy-number profile of tumor specimen ALCH-B1ZN-TTP1-A from ALCHEMIST case ALCH-B1ZN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.4 years (20,960 days).
Specimen ALCH-B1ZN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a176877f-1c3e-4690-9828-48149630a57d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1ZN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/2f03446d-d1f5-4336-8d14-0c5f14245752

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 8,398; copy number 2: 47,926; copy number 3: 2,534; copy number 4: 2; copy number 8: 2; copy number 9: 2; copy number 16: 1; copy number 21: 4; copy number 25: 1; copy number 43: 1.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr7:99,598,267–99,611,045, 1 gene (within-gene range 0–2): TMEM225B.
- chr9:21,278,050–22,128,103, 36 genes: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,341,859, 1 gene, copy number 25: CR383658.1.
- chr16:33,495,943–33,570,935, 5 genes, copy number 21–43: AC136944.5, AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr22:18,361,820–18,391,105, 2 genes, copy number 8: FAM230J, AC011718.1.
- chr22:18,533,646–18,577,968, 1 gene, copy number 16: PI4KAP1.
- chr22:18,636,445–18,653,617, 2 genes, copy number 9: CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 5,548. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
